Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6A-01A from TCGA case TCGA-VQ-AA6A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 56.8 years (20,764 days).
Specimen TCGA-VQ-AA6A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7ba6f978-15a2-4479-8ad3-184b3ce3ca87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0434d8b4-1361-4e65-ad1d-5af2bb117bf8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 8,817; copy number 3: 17,625; copy number 4: 19,130; copy number 5: 5,788; copy number 6: 5,429; copy number 7: 769; copy number 8: 260; copy number 9: 1,504; copy number 10: 33; copy number 11: 20; copy number 13: 16; copy number 14: 234; copy number 15: 86; copy number 16: 20; copy number 17: 12; copy number 18: 12; copy number 22: 9; copy number 29: 3; copy number 30: 16; copy number 53: 28; copy number 59: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6A-01A-11D-A40Z-01): tumor purity 0.8, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:2,717,510–2,730,037, 1 gene: KCNV2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,994 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,539,465–11,099,869, 53 genes, copy number 9 (within-gene range 2–9): SLC25A33, AL954705.1, TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2, CLSTN1, MZT1P1, AL357140.3, CTNNBIP1, AL357140.1, AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1.
- chr1:11,785,723–16,972,964, 190 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:28,481,362–29,146,994, 31 genes, copy number 10: RNU6ATAC27P, RCC1, SNHG3, SNORA73A, SNORA73B, PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A, TAF12, RAB42, LINC01715, AL360012.1, RNU11, GMEB1, AL645729.1, YTHDF2, OPRD1, AL009181.1, Y_RNA, EPB41, AL138785.1, Y_RNA, Metazoa_SRP, TMEM200B, AL357500.1.
- chr1:107,571,161–108,244,081, 8 genes, copy number 11 (within-gene range 3–11): VAV3, MIR7852, VAV3-AS1, LINC02785, SLC25A24, AL359258.2, AL359258.3, NBPF4.
- chr1:112,820,170–114,035,572, 28 genes, copy number 11–13 (within-gene range 3–13): LINC01356, LINC01357, AL390729.1, SLC16A1, AKR7A2P1, SLC16A1-AS1, AL390242.1, LRIG2-DT, LRIG2, RLIMP2, AL357055.1, AL357055.2, MAGI3, AL391058.1, MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15, AP4B1, DCLRE1B, HIPK1-AS1, HIPK1, OLFML3, AL591742.1.
- chr4:87,160,103–87,240,314, 2 genes, copy number 10 (within-gene range 5–10): KLHL8, AC092658.1.
- chr7:70,972–57,275,197, 1,049 genes, copy number 9 (broad region; genes not listed).
- chr7:91,030,149–92,401,383, 20 genes, copy number 16: AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1.
- chr7:95,772,506–105,600,875, 294 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr7:108,994,031–122,144,255, 146 genes, copy number 9–29 (within-gene range 4–29) (broad region; genes not listed).
- chr8:32,911,493–34,865,364, 31 genes, copy number 9: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288.
- chr10:43,077,064–43,674,703, 25 genes, copy number 9: RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3, CAP1P2, ZNF485, ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1.
- chr17:72,021,851–73,644,445, 28 genes, copy number 18–30 (within-gene range 8–30): ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1.
- chr18:6,727,053–9,020,764, 39 genes, copy number 14–22: AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19.
- chr18:12,738,965–13,185,617, 12 genes, copy number 17: AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2.
- chr18:20,946,906–22,348,252, 38 genes, copy number 9–59: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
